Surgical pathology report (de-identified scan), TCGA case TCGA-CV-A464, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-A464-01A (Primary Tumor).

[page 1 of 4]
M

Accession:

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT BUCCAL:

INVASIVE SQUAMOUS CARCINOMA - Well to moderately differentiated

Tumor Features:

Gross: Ulcerating

Size: 4.4 cm in largest dimension (by microscopic review)

Invasion: Present, depth 1.1 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: PRESENT, EXTENSIVE INCLUDING LARGE NERVE BUNDLES (A15,16)

Vascular Invasion: Absent

Mucosal Margins: (en-face) POSITIVE FOR INVASIVE CARCINOMA (SUPERIOR, ANTERIOR AND INFERIOR)

Deep Margin: (radial) POSITIVE FOR INVASIVE CARCINOMA

(B) POSTERIOR LEFT MASTOID TUBEROSITY:

Squamous mucosa, negative for tumor

Bone evaluation pending decalcification and will be reported in an addendum.

ICD-O-3

(C) LEFT BUCCAL FAT:

Additional sections pending review, see addendum.

Carcinoma, Squamous cell, NOS 8070/3

Site: buccal mucosa C06.0

(D) LEFT POSTERIOR SUPERIOR MARGIN:

INVASIVE SQUAMOUS CARCINOMA PRESENT

(E) NEW POSTERIOR MARGIN, LEFT:

Squamous mucosa with underlying salivary glands, negative for tumor.

hw
10/1/12

(F) SUBMENTAL LYMPH NODE:

Three lymph nodes, negative for tumor (0/3).

(G) LEFT NECK DISSECTION, LEVEL I:

Twelve lymph nodes, negative for tumor (0/12).

Benign salivary gland.

(H) NEW ANTERIOR MARGIN:

Squamous mucosa and skeletal muscle, negative for tumor.

(I) NEW INFERIOR MARGIN:

Squamous mucosa, negative for tumor.

(J) NEW SUPERIOR MARGIN:

Squamous mucosa with underlying salivary glands, negative for tumor.

(K) NEW DEEP MARGIN:

Skeletal muscle, negative for tumor.

(L) LEFT NECK DISSECTION, LEVEL II:

Fibroadipose tissue, negative for lymphoid tissue or tumor.

[page 2 of 4]
Accession:
Specimen Date/Time:

(M) LEFT SELECTIVE NECK DISSECTION, LEVEL III:
Eighteen lymph nodes, negative for tumor (0/18).

(N) LEFT SELECTIVE NECK DISSECTION, LEVEL IV:
Four lymph nodes, negative for tumor (0/4).

GROSS DESCRIPTION

(A) EXCISION, LEFT BUCCAL CANCER - An oval portion of mucosa and underlying soft tissue (4.4 x 3.2 x 1.1 cm) shows a disrupted mucosal surface which is markedly erythematous over greater than 80% of the mucosal surface, predominantly focused in the central and posterior aspects. The irregular mucosal surface corresponds to an ill-defined tumor (3.4 x 1.8 x 1.1 cm). The tumor is within 1.0 mm of the deep surface which shows fibroadipose tissue and skeletal muscle. The specimen is oriented in relationship to the additional specimens, part B, D and E, by the surgeon.

SECTION CODE: A1, superior anterior mucosal margin, en face (anterior to specimen B, D, E); A2, anterior margin, en face; A3, A4, inferior margin, en face, from anterior then posterior; A5-A8, perpendicular sections of tumor and deep margin (blue) from posterior to anterior; A9-A16, serially remainder of specimen from anterior to posterior.

*FS/DX: INVASIVE SQUAMOUS CARCINOMA AT SUPERIOR, ANTERIOR AND INFERIOR MARGINS

(B) POSTERIOR LEFT MAXILLARY TUBEROSITY - One pale-gray bone tissue, 2.0 x 1.5 x 1.0 cm, with two teeth.
SECTION CODE: B1, superior margin submitted for frozen section; B2, pieces of soft tissue from the area surrounding the teeth; B3, possible bone margin of one side of the teeth; B4, the other side of the possible bone margin; B5, the possible bone margin overlying the teeth. Representatively submitted.

*FS/DX: NEGATIVE FOR TUMOR.

(C) LEFT BUCCAL FAT - A single fragment of fatty tissue, 4.0 x 3.0 x 0.7 cm. Entirely submitted in C1-C3.

(D) LEFT POSTERIOR SUPERIOR MARGIN, MARGIN IS INKED - a 1.3 x 0.7 x 0.5 cm portion of pink soft tissue oriented with dye designating the true margin. Entire specimen submitted en face, for frozen section diagnosis in D.

*FS/DX: SQUAMOUS CELL CARCINOMA.

(E) NEW POSTERIOR MARGIN LEFT, INK AT TRUE MARGIN, STITCH SUPERIOR - Received is a 2.5 x 1.7 x 0.5 cm portion of pink soft tissue that is oriented by the surgeon with ink at the true margin and a stitch designating superior. The superior aspect is inked blue. Entire specimen, submitted en face, for frozen section diagnosis in E.

*FS/DX: NEGATIVE FOR TUMOR.

(F) SUBMENTAL LYMPH NODE - Single fragment of fatty tissue measuring 4.5 x 2.5 x 1.0 cm. Sectioning reveals four possible lymph nodes ranging from 0.3 x up to 0.4 cm in greatest dimension. Possible lymph nodes are entirely submitted in F - four possible lymph nodes.

(G) LEFT NECK DISSECTION, LEVEL I - Received is a submandibular gland measuring 5.0 x 3.0 x 2.5 cm and attached fragment of fatty tissue. Sectioning reveals multiple possible lymph nodes ranging from 0.6 x up to 0.8 cm in greatest dimension. Cut surface of the submandibular gland is unremarkable. Entire possible lymph nodes and representative sections of the submandibular are submitted.

SECTION CODE: G1, five possible lymph nodes; G2, one possible lymph node; G3, one sectioned possible lymph node; G4, one sectioned possible lymph node; G5, sections of the submandibular gland.

(H) NEW ANTERIOR MARGIN, INK AT THE TRUE MARGIN, STITCH SUPERIOR - Received is a 3.0 x 0.6 x 0.6 cm mucosa-covered soft tissue fragment with stitch designating superior end. The specimen is inked and entirely submitted.

INK CODE: Blue - superior end, with stitch; orange - the opposite end.

SECTION CODE: H1, superior margin with new margin; H2, opposite margin with new margin.

*FS/DX: NEGATIVE.

(I) NEW INFERIOR MARGIN, TRUE MARGIN INKED - a 1.1 x 0.7 x 0.1 cm mucosa-covered oriented soft tissue fragment. Margin submitted en face in I.

*FS/DX: NEGATIVE FOR TUMOR.

(J) NEW SUPERIOR MARGIN, STITCH ANTERIOR, INK AT TRUE MARGIN - Received is a 3.0 x 1.0 x 0.6 cm mucosa-covered soft tissue fragment. The margin submitted en face for frozen section in J.

[page 3 of 4]
M

Accession:
Specimen Date/Time:

*FS/DX: NEGATIVE FOR TUMOR.

(K) NEW DEEP MARGIN, INK AT TRUE MARGIN - red soft tissue, 2.0 x 1.8 x 0.4 cm, entirely submitted enface in K.

*FS/DX: MUSCLE, NEGATIVE FOR TUMOR.

(L) LEFT NECK DISSECTION, LEVEL II - A single fragment of fatty tissue measuring 3.0 x 2.5 x 1.5 cm. Sectioning reveals three possible lymph nodes ranging from 0.5 up to 1.0 cm in greatest dimension. Entire lymph node and the rest of the fatty tissue are entirely submitted.

SECTION CODE: L1, one possible lymph node; L2, one bisected possible lymph node; L3, one bisected possible lymph node; L4, L5, the rest of the fatty tissue.

(M) LEFT SELECTIVE NECK DISSECTION, LEVEL III - Received is a single fragment of fatty tissue measuring 6.0 x 3.5 x 1.8 cm. Sectioning reveals multiple possible lymph nodes ranging from 0.4 up to 1.5 cm in greatest dimension. Possible lymph nodes are entirely submitted.

SECTION CODE: M1, five possible lymph nodes; M2, three possible lymph nodes; M3, three possible lymph nodes; M4, one sectioned possible lymph node; M5, one sectioned possible lymph node; M6, one sectioned possible lymph node; M7, one sectioned possible lymph node.

(N) LEFT SELECTIVE NECK DISSECTION, LEVEL IV - A single fragment of fatty tissue measuring 4.0 x 2.0 x 0.8 cm. Possible lymph nodes are entirely submitted.

SECTION CODE: N1, two possible lymph nodes; N2, one bisected possible lymph node; N3, one bisected possible lymph node.

CLINICAL HISTORY

Squamous cell carcinoma left buccal mucosa.

SNOMED CODES

T-51300, M-80703, T-51004

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 4 of 4]
M

Accession:
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(B) POSTERIOR LEFT MASTOID TUBEROSITY:
Squamous mucosa, negative for tumor
Bone and bone margins, negative for tumor.

(C) LEFT BUCCAL FAT:
Fibroadipose tissue, negative for tumor.

COMMENT

Additional sections reviewed following decalcification in part B.
Additional levels were reviewed on Part C.

Entire report and diagnosis completed by:

-----END OF REPORT-----

Division of Pathology and Laboratory Medicine

II/III/IV Discrepancy		☒

9/11/12

Source: NCI Genomic Data Commons file bd62c473-b0d0-415f-8bbc-44e69ea0c9f5 (TCGA-CV-A464.F2B9BEF8-AEE4-4F8B-9AE4-49B41FECF036.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).